FM case AD3006 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/06096868-63aa-4b1d-97aa-5eab24fe3c2f

Female, 49.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
